Somatic mutation profile of tumor specimen TCGA-EJ-A46E-01A (aliquot TCGA-EJ-A46E-01A-31D-A257-08) from TCGA case TCGA-EJ-A46E, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.6 years (21,054 days).
Specimen TCGA-EJ-A46E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6de5666a-f88f-466c-8de3-a1c21ee15805.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A46E-10A (Blood Derived Normal), aliquot TCGA-EJ-A46E-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c300fb31-f8f9-416f-8afe-41771b8d82ce

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGF16 | c.396A>T p.E132D | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.099); catalogued as rs782233147, COSV71546316; called by muse, mutect2
